Gene-level copy-number profile of tumor specimen TCGA-99-8025-01A from TCGA case TCGA-99-8025, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 72.9 years (26,634 days).
Specimen TCGA-99-8025-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.bd8bb0ff-ae2e-48de-a978-805c9fe7d7e9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-99-8025-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5638a87a-a61a-4cf1-8fc9-e2825123b215

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 503; copy number 2: 1,133; copy number 3: 16,895; copy number 4: 16,666; copy number 5: 4,940; copy number 6: 8,777; copy number 7: 3,561; copy number 8: 4,208; copy number 9: 2,790; copy number 10: 312; copy number 13: 25.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-99-8025-01A-11D-2237-01): tumor purity 0.43, ploidy 4.47, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,127 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,218,417–205,134,950, 1,386 genes, copy number 9 (broad region; genes not listed).
- chr7:75,533,298–97,972,985, 312 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).
- chr7:102,748,971–148,420,998, 834 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr8:127,735,434–129,844,504, 25 genes, copy number 13 (within-gene range 7–13): MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686, AC103718.1, MTRF1LP2, GSDMC, AC022973.5.
- chr11:112,961,247–113,278,436, 1 gene, copy number 9 (within-gene range 8–9): NCAM1.
- chr11:113,265,137–119,729,200, 201 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr17:51,336,646–55,327,791, 29 genes, copy number 9 (within-gene range 8–9): LINC02073, RPL7P48, CA10, AC002090.1, LINC01982, LINC02089, LINC02876, MTCO1P40, AC034268.2, AC005341.1, AC090079.1, AC090079.2, AC034268.1, RPS2P48, KIF2B, AC023934.1, ISCA1P3, AC015943.1, AC005951.1, ARL2BPP8, RN7SKP14, TOM1L1, COX11, AC007485.2, AC007485.1, STXBP4, HLF, AC007638.2, AC007638.1.
- chr19:36,034,984–42,670,816, 339 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 503. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
